Surgical pathology report (de-identified scan), TCGA case TCGA-AF-4110, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-4110-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Sigmoid and upper rectum
- B. Appendix

CLINICAL NOTES

PRE-OP DIAGNOSIS: Sigmoid cancer.

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "sigmoid and upper rectum" is a rectosigmoid colon, partially covered with abundant yellow lobular fat. The specimen is

38.5. The proximal end is inked blue and is previously stapled. The

distal end is also stapled and is inked black. The serosa is pink-tan smooth glistening and partially covered with abundant yellow lobular fat. There is a 3.0 x 2.5 cm. umbilication which comes within 7.5 cm. of distal margin. This umbilication is inked blue. The retroperitoneal reflection is located 4 cm. from the distal margin. The specimen is opened to show pink-tan smooth glistening mucosa with normal to slightly dilated folds. The proximal end has a circumference of 5 cm. The distal end has a circumference of 9.5 cm. There is a small exophytic polyp measuring

0.7 cm. in greatest dimension, this is located 13 cm. from the proximal margin. There is also a circumferential lesion located subjacent to the umbilication measuring 6.0 x 6.0 x 1.2 cm. This comes within 6.5 cm. of the distal margin and on cut surface shows invasion into the muscularis propria, contiguous with the umbilicated serosa and approximately 3 cm. of the radial margin (radial margin inked blue). There are lymph nodes subjacent to the tumor which are large and slightly necrotic. Additional lymph nodes

are grossly identified in the specimen. Representative sections of the specimen are submitted as follows: Block 1 - representative luminal margins; block 2 - entire small polyp; block 3-5 - representative section of tumor including tumor to normal, tumor to deep; block 6 - radial margin; block 7 - possible tumor in vessel;

GROSS DESCRIPTION

block 8 - nine possible lymph nodes; block 9 - eight possible lymph nodes; block 10 - six possible lymph nodes; block 11 - five possible lymph nodes; block 12 - four possible lymph nodes; block 13 - three possible lymph nodes; block 14 - representative section of additional tumor in possible vessel (5 cm. in length); block 15 - representative section of possible mottled lymph node (5 cm. in greatest dimension). RS-15. [REDACTED]

[page 2 of 3]
[REDACTED]

B. Received in formalin, labeled "appendix" is an unremarkable, 6.6 cm. appendix surfaced by smooth tan pink serosa with a copious amount of attached mesoappendix. The specimen ranges from 0.5 to 0.7 cm. in diameter with a pinpoint lumen on sectioning. The mucosa is unremarkable, tan pink and the wall averages 0.2 cm. in thickness. No transmural defect is identified. The proximal margin and bisected distal tip are submitted in one block. RS-1. [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A. Summary of colon and rectum microscopic findings:
Histologic type: Invasive adenocarcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): Tumor penetrates to the surface of the visceral peritoneum (serosa). No direct invasion of other structures identified. (pT4a).
Proximal margin: Negative for tumor.
Distal margin: Negative for tumor.
Circumferential (radial) margin: The mesenteric margin is negative for tumor. Distance of tumor from closest margin: 6.5 cm from distal margin
Vascular invasion: Very prominent invasion into large venous spaces
is noted both directly adjacent to the tumor and in the pericolonic

MICROSCOPIC DESCRIPTION

fat. Focal lymphatic space invasion is also noted.
Regional lymph nodes (pN): Prominant metastatic tumor is identified in 21 of 34 lymph node (pN2b).
Non-lymph node pericolonic tumor: Present.
Distant metastasis (pM): Could not evaluate, pMx.
Other findings: A small serrated adenoma is present and focal diverticulitis is noted.
B. Microscopic examination reveals unremarkable appendix with fibrous obliteration of the tip.

5x1, 1x1, [REDACTED]

[page 3 of 3]
DIAGNOSIS

- A. Colon, sigmoid, rectum, excision:
Moderately differentiated invasive adenocarcinoma, invasive
of visceral peritoneum (pT4a).
Metastatic adenocarcinoma present in 21 of 34 lymph nodes
(pN2b).
Extranodal tumor present and prominent venous space invasion
present.
Resection margins are negative for tumor.
- B. Appendix, excision:
Unremarkable appendix.
-

Source: NCI Genomic Data Commons file 6063e0ec-aa99-4411-9c30-c6f156a92576 (TCGA-AF-4110.A08BBAB4-C3F6-4807-B300-E418F85A2A41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).